Somatic mutation profile of tumor specimen TCGA-3Z-A93Z-01A (aliquot TCGA-3Z-A93Z-01A-11D-A36X-10) from TCGA case TCGA-3Z-A93Z, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.0 years (25,205 days).
Specimen TCGA-3Z-A93Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64250535-04da-466e-9967-15e7b4f8fbd6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3Z-A93Z-10A (Blood Derived Normal), aliquot TCGA-3Z-A93Z-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6299311-46e8-4a34-a6fd-33e8536e4acd

The open-access MAF lists 88 somatic variants for this specimen: 71 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 15, Frame Shift Del 6, Nonsense Mutation 5, Splice Site 4, Intron 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAG1 | c.2210G>A p.R737H | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs104894286, CM981696; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- VHL | c.343C>A p.H115N | Missense Mutation (SNP) | VAF 29/104 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as CD141839, CM961423, CM982005, COSV56545369, COSV56546151, COSV56556158, COSV56571206; called by muse, mutect2, varscan2
- AGL | c.4116G>A p.W1372* | Nonsense Mutation (SNP) | VAF 44/169 reads (26%) | catalogued as COSV99649234; called by muse, varscan2
- AKR1A1 | c.517C>T p.L173F | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs761048161, COSV100698726; called by muse, mutect2, varscan2
- AMD1 | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100924491; called by muse, mutect2, varscan2
- ANKS6 | c.2032T>G p.L678V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100782285; called by muse, mutect2, varscan2
- AP5M1 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 42/197 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV55105010; called by muse, mutect2, varscan2
- ARID3B | c.899A>G p.Y300C | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60558627; called by muse, mutect2, varscan2
- BHMT | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as COSV99165425; called by muse, mutect2, varscan2
- BRPF3 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV60209438; called by muse, mutect2, varscan2
- CATSPER2 | c.392T>A p.L131* | Nonsense Mutation (SNP) | VAF 32/169 reads (19%) | catalogued as COSV100390740; called by muse, mutect2, varscan2
- CGREF1 | c.719-10_758del p.X240_splice (on ENST00000260595; = p.G254Rfs*30 on NM_006569.6 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 18/133 reads (14%) | catalogued as rs1558457056; called by mutect2, varscan2*
- CLDN5 | c.292A>T p.T98S (on ENST00000618236 / NM_001363066.2; = p.T183S on NM_003277.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.01); catalogued as COSV99596706; called by muse, mutect2
- CTDP1 | c.2069-1G>T p.X690_splice | Splice Site (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99310614; called by muse, mutect2, varscan2
- CTSA | c.329T>C p.L110P | Missense Mutation (SNP) | VAF 111/327 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51942695; called by muse, mutect2, varscan2
- DOCK7 | c.4328G>A p.R1443K (on ENST00000635253 / NM_001367561.1; = p.R1412K on NM_033407.3) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV99224459; called by muse, mutect2, varscan2
- EHMT1 | c.3853G>A p.G1285S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.435); catalogued as rs758900811, COSV66044811; called by muse, mutect2, varscan2
- ENTPD2 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.426); catalogued as rs761509448, COSV100445768; called by muse, mutect2, varscan2
- GLIS2 | c.1439T>C p.L480P | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99267534; called by muse, mutect2, varscan2
- HECTD1 | c.945A>C p.R315S | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101237387; called by muse, mutect2, varscan2
- HTATSF1 | c.1424G>T p.G475V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV99511656; called by muse, mutect2, varscan2
- ICAM3 | c.731A>G p.D244G | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.044); catalogued as rs750746896, COSV99349070; called by muse, mutect2, varscan2
- IGSF10 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV99180029; called by muse, varscan2
- ITPR1 | c.5702C>A p.A1901D (on ENST00000354582; = p.A1846D on NM_002222.7) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.579); catalogued as COSV100231222; called by muse, mutect2, varscan2
- KCNJ14 | c.409G>T p.A137S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs866907833, COSV100655769, COSV60738864; called by muse, mutect2, varscan2
- KRT1 | c.1873T>A p.S625T | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99358782; called by muse, varscan2
- KRT71 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99922168; called by muse, mutect2, varscan2
- KRT71 | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99922170; called by muse, mutect2, varscan2
- LENEP | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV99422506; called by muse, mutect2, varscan2
- LFNG | c.86G>T p.R29M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); catalogued as COSV101273422; called by muse, mutect2, varscan2
- LRP1B | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV101257165; called by muse, mutect2, varscan2
- MAP4K4 | c.3383C>G p.T1128R (on ENST00000347699 / NM_001242559.2; = p.T1054R on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV100154773; called by muse, mutect2, varscan2
- MDFIC | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 58/297 reads (20%) | catalogued as COSV99995145; called by muse, varscan2
- MED1 | c.4451A>T p.D1484V | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100327830; called by muse, mutect2, varscan2
- MPO | c.1638C>G p.I546M | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV99228805; called by muse, mutect2, varscan2
- MUC4 | c.2589G>T p.M863I | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); catalogued as COSV100640543; called by muse, mutect2, varscan2
- MXRA5 | c.2696C>T p.T899I | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as COSV99477010; called by muse, mutect2, varscan2
- MYCBP2 | c.4975G>A p.A1659T (on ENST00000357337; = p.A1697T on NM_015057.5) | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV100630401; called by muse, mutect2, varscan2
- NLRP14 | c.909A>T p.L303F | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100205000; called by muse, mutect2
- NMT2 | c.1199T>C p.L400P | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100975544; called by muse, mutect2, varscan2
- NOTCH1 | c.5972G>A p.R1991H | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1371022203; ClinVar: uncertain significance; called by muse, mutect2
- NT5M | c.250C>A p.L84M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV101198590; called by muse, varscan2
- NT5M | c.251T>G p.L84R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV101198593; called by muse, varscan2
- NUP133 | c.2157T>G p.I719M | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV99772934; called by muse, mutect2, varscan2
- PHF5A | c.110T>A p.V37E | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV99346808; called by muse, mutect2, varscan2
- PIK3CD | c.2718+1G>C p.X906_splice | Splice Site (SNP) | VAF 28/102 reads (27%) | catalogued as COSV100740182; called by muse, mutect2, varscan2
- PLEKHG3 | c.3124T>A p.C1042S (on ENST00000394691; = p.C1098S on NM_001308147.2) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.781); catalogued as COSV99906614; called by muse, mutect2, varscan2
- POLR3H | c.598T>C p.W200R | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771959676, COSV99347411; called by mutect2, varscan2
- PVRIG | c.479C>G p.A160G | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV99443853; called by muse, mutect2, varscan2
- PXMP2 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs768194577, COSV100443525; called by muse, mutect2
- RBM33 | c.546T>A p.N182K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV99841245; called by muse, mutect2, varscan2
- RBMXL1 | c.641A>T p.Y214F | Missense Mutation (SNP) | VAF 52/254 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV99556223; called by muse, mutect2, varscan2
- RGL1 | c.610+2T>C p.X204_splice (on ENST00000360851 / NM_001297672.2; = p.X239_splice on NM_015149.5 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 18/80 reads (23%) | catalogued as COSV100486779; called by mutect2, varscan2
- SCARA3 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs140895596; called by muse, mutect2, varscan2
- SLC27A2 | c.1341G>C p.K447N | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV51060271, COSV99982842; called by muse, mutect2, varscan2
- SLC35F1 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as COSV100837747, COSV64498307; called by muse, mutect2, varscan2
- SMG5 | c.638T>C p.M213T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV100700780; called by muse, mutect2, varscan2
- SMURF1 | c.154G>C p.D52H | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100742460; called by muse, mutect2, varscan2
- STBD1 | c.998G>C p.R333P | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99421519; called by muse, mutect2, varscan2
- THBS1 | c.2131T>C p.Y711H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV52950396; called by muse, mutect2, varscan2
- TINAG | c.1369T>C p.S457P | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs368359804; called by muse, mutect2, varscan2
- TNRC6B | c.864T>G p.S288R | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100109710; called by muse, mutect2, varscan2
- VLDLR | c.973A>T p.K325* | Nonsense Mutation (SNP) | VAF 27/113 reads (24%) | catalogued as COSV101173226; called by muse, mutect2, varscan2
- ZNF337 | c.1653A>C p.K551N | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV99430193; called by muse, varscan2
- ARVCF | c.2600del p.G867Afs*24 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- C2orf78 | c.1594del p.V532Lfs*13 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- CREB3L2 | c.1202_1208del p.Y401Lfs*22 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- MYH14 | c.82del p.L28Cfs*72 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | called by mutect2, pindel, varscan2
- PABPC3 | c.1390del p.S464Lfs*77 | Frame Shift Del (DEL) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- PTPN13 | c.1570del p.I524Lfs*3 | Frame Shift Del (DEL) | VAF 43/274 reads (16%) | called by mutect2, pindel, varscan2
- RALGAPA1 | c.5628_5639del p.E1877_F1880del | In Frame Del (DEL) | VAF 22/126 reads (17%) | called by mutect2, pindel, varscan2
- ASB15 | c.852C>T p.A284= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as COSV99306541; called by muse, mutect2, varscan2
- B3GALT4 | c.252G>A p.L84= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV101005631, COSV65851449; called by muse, mutect2, varscan2
- CCPG1 | c.1156C>T p.L386= | Silent (SNP) | VAF 49/235 reads (21%) | catalogued as COSV51244649, COSV99380380; called by muse, mutect2, varscan2
- COPS8 | c.513C>T p.A171= | Silent (SNP) | VAF 69/270 reads (26%) | catalogued as COSV100585394; called by muse, mutect2, varscan2
- CORIN | c.2349T>G p.L783= | Silent (SNP) | VAF 42/186 reads (23%) | catalogued as COSV99903649; called by muse, mutect2, varscan2
- DDC | c.915A>T p.L305= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs773845696, COSV100779329; called by muse, mutect2, varscan2
- FBXL8 | c.267C>T p.A89= | Silent (SNP) | VAF 43/153 reads (28%) | catalogued as COSV99263518; called by muse, mutect2, varscan2
- HEATR5B | c.3867A>G p.V1289= | Silent (SNP) | VAF 94/264 reads (36%) | catalogued as rs540789339, COSV99249312; called by muse, mutect2, varscan2
- LARP7 | c.588A>G p.K196= | Silent (SNP) | VAF 62/315 reads (20%) | catalogued as rs774358467, COSV100135147; called by muse, mutect2, varscan2
- NUTM2D | c.786A>T p.R262= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- PKP1 | c.1461C>T p.D487= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs149333889; called by muse, mutect2, varscan2
- PLEKHA2 | c.663A>T p.A221= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1458471213, COSV101173418; called by muse, mutect2, varscan2
- STBD1 | c.999C>A p.R333= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV99421523; called by muse, mutect2, varscan2
- UBP1 | c.1275G>A p.S425= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV99372689; called by muse, mutect2, varscan2
- ZMIZ1 | c.2805G>A p.E935= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100566103; called by muse, mutect2, varscan2
- AC116366.2 | c.-638+11029C>T | Intron (SNP) | VAF 69/192 reads (36%) | catalogued as rs1274158976, COSV61818990; called by muse, mutect2, varscan2
- SYNPO | chr5:150656948 C>G | 3'Flank (SNP) | VAF 9/59 reads (15%) | catalogued as COSV99770757; called by muse, mutect2, varscan2
